Somatic mutation profile of tumor specimen 0DEP1T from CCDI case PBBPTS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 3.8 years (1,406 days).
Specimen 0DEP1T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c118c3-10aa-4520-96d0-d02b32b37867.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEP22 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91733c08-b775-42d0-8ce8-e96b3391f5c8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*918G>A | 3'UTR (SNP) | VAF 34/362 reads (9%) | catalogued as rs121913113, CM065183, COSV53404768; ClinVar: pathogenic; called by muse, mutect2
- BRCA1 | c.5206G>A p.V1736I | Missense Mutation (SNP) | VAF 66/836 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- CFAP74 | c.900_901insTA p.K301* | Frame Shift Ins (INS) | VAF 104/367 reads (28%) | called by mutect2, varscan2
- EZHIP | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 260/306 reads (85%) | SIFT tolerated (0.23); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- EZHIP | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 110/132 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.271); called by muse, mutect2
